CCDI case PBCDWK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/5d184f3e-ba9d-488a-a4c6-9f171dda8be2

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.0 years (351 days).

Biospecimens (3 samples)
- Sample 0DPSN2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPSNB: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPSNK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
